FM case AD2414 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/ee69760e-795f-461b-993c-8f5123bcaf3e

Male, 44.5 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the cardia. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
